Somatic mutation profile of tumor specimen C3N-03764-02 (aliquot CPT0246030006) from CPTAC case C3N-03764, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.1 years (25,223 days).
Specimen C3N-03764-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a6cdc4-b5f4-47e5-9985-f785b96289dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03764-31 (Blood Derived Normal), aliquot CPT0246070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e02444f-2be2-481e-ae3f-550c24e9c532

The open-access MAF lists 274 somatic variants for this specimen: 182 protein-altering or splice-affecting, 53 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 53, Intron 23, Nonsense Mutation 14, Frame Shift Del 8, RNA 7, 5'UTR 5, Splice Site 3, Splice Region 2, In Frame Del 2, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 96/277 reads (35%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB9 | c.1541G>A p.R514H (on ENST00000280560 / NM_019625.4; = p.R471H on NM_019624.3) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs756697048, COSV99757690; called by muse, mutect2, varscan2
- ADCY2 | c.1861G>T p.V621L | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.428); catalogued as rs149172094; called by muse, mutect2, varscan2
- ADGB | c.59C>G p.S20W | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as rs1161187596; called by muse, mutect2, varscan2
- ADGRE5 | c.1273G>A p.E425K (on ENST00000242786 / NM_078481.4; = p.E332K on NM_001784.5) | Missense Mutation (SNP) | VAF 92/351 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs772157605, COSV54410429; called by muse, mutect2, varscan2
- ARID2 | c.4468G>T p.G1490* | Nonsense Mutation (SNP) | VAF 58/202 reads (29%) | catalogued as rs1174556277, COSV100536340; called by muse, mutect2, varscan2
- C6orf62 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.981); catalogued as COSV100016196; called by muse, mutect2
- CACNA1B | c.6592C>G p.R2198G | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV53125203; called by muse, mutect2, varscan2
- CASKIN1 | c.1571_1573del p.K524del | In Frame Del (DEL) | VAF 24/204 reads (12%) | catalogued as rs1223851396; called by pindel, varscan2
- CCDC39 | c.1397C>A p.S466* | Nonsense Mutation (SNP) | VAF 41/252 reads (16%) | catalogued as COSV56486476; called by muse, mutect2, varscan2
- CCDC88A | c.1084A>G p.M362V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs765431034; called by muse, mutect2, varscan2
- CDH9 | c.884C>G p.P295R | Missense Mutation (SNP) | VAF 76/457 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.094); catalogued as COSV50342707; called by muse, mutect2, varscan2
- CDHR4 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs368345757; called by muse, mutect2
- CELSR3 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 38/451 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs201047576; called by muse, mutect2
- CLCN1 | c.1564G>T p.G522W | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58371515; called by muse, mutect2, varscan2
- CNTNAP3 | c.3545C>A p.A1182E | Missense Mutation (SNP) | VAF 24/462 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1299094448; called by muse, mutect2
- CST1 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1362388192, COSV59055717; called by muse, mutect2
- CTNNA2 | c.2362C>A p.Q788K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58146912; called by muse, mutect2, varscan2
- CYP2D7 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 32/602 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs541031533, COSV100809660; called by muse, mutect2
- DIAPH3 | c.3215G>T p.G1072V (on ENST00000400324 / NM_001042517.2; = p.G809V on NM_030932.3) | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57364683; called by muse, mutect2, varscan2
- ENO1 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as rs533860041; called by muse, mutect2, varscan2
- EPC2 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1158947178; called by muse, mutect2, varscan2
- FAM135B | c.3572C>A p.T1191K | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99421984; called by muse, mutect2
- FLG2 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 103/673 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs747918610; called by muse, mutect2, varscan2
- FPR1 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59054029; called by muse, mutect2, varscan2
- FURIN | c.1918G>A p.V640I | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs756901366; called by muse, mutect2
- GGN | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.551); catalogued as rs771741257; called by muse, mutect2, varscan2
- GPR20 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs914222660; called by muse, mutect2, varscan2
- HRNR | c.2894G>C p.G965A | Missense Mutation (SNP) | VAF 230/1003 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.346); catalogued as rs566347548; called by muse, mutect2, varscan2
- HRNR | c.2561C>A p.S854Y | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758727210; called by muse, mutect2, varscan2
- KCNB1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65569828; called by muse, mutect2, varscan2
- KIF20B | c.4235G>A p.W1412* (on ENST00000371728 / NM_001284259.2; = p.W1372* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs1423940708, COSV53304189; called by muse, mutect2, varscan2
- LBHD1 | c.509G>C p.C170S (on ENST00000431002 / NM_001367940.1; = p.C144S on NM_024099.3) | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.169); catalogued as rs773862019; called by muse, mutect2, varscan2
- MAGEC2 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV55998335, COSV56000976; called by muse, mutect2, varscan2
- MEI1 | c.2609T>A p.L870Q | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55902056; called by muse, mutect2, varscan2
- MGAT3 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774059231; called by muse, mutect2
- MMP17 | c.1197C>A p.F399L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.601); catalogued as COSV62180762; called by muse, mutect2, varscan2
- MSH2 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 30/415 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751125, COSV51878543; ClinVar: uncertain significance; called by muse, mutect2
- MUC16 | c.43151G>A p.R14384K | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as rs1032572547; called by muse, mutect2, varscan2
- MYO3A | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.346); catalogued as COSV56331236; called by muse, mutect2, varscan2
- NEDD9 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV65159374; called by muse, mutect2, varscan2
- NEU2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 104/425 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs930082544; called by muse, mutect2, varscan2
- NRXN1 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV68002191; called by muse, mutect2, varscan2
- PCSK6 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100082966, COSV100083110; called by muse, mutect2, varscan2
- PLEC | c.2966C>T p.P989L (on ENST00000322810 / NM_201380.4; = p.P879L on NM_000445.5) | Missense Mutation (SNP) | VAF 45/447 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554713184; called by muse, mutect2, varscan2
- PPIG | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.422); catalogued as rs754250086, COSV53642652; called by muse, mutect2, varscan2
- PPP1R16A | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs369711109, COSV52952275; called by muse, mutect2
- PRKDC | c.7486C>T p.Q2496* | Nonsense Mutation (SNP) | VAF 32/159 reads (20%) | catalogued as rs1356241356; called by muse, mutect2, varscan2
- PWWP3B | c.1309A>G p.R437G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61798189; called by muse, mutect2, varscan2
- RAB6B | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1179735181, COSV99557700; called by muse, mutect2, varscan2
- RGS4 | c.500G>C p.R167P | Missense Mutation (SNP) | VAF 103/642 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100905595, COSV63357266, COSV63357554; called by muse, mutect2, varscan2
- STK33 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs537936728, COSV59404147; called by muse, mutect2, varscan2
- SYT10 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99951456; called by muse, mutect2, varscan2
- TBX3 | c.1229C>A p.P410H (on ENST00000257566 / NM_016569.4; = p.P390H on NM_005996.4) | Missense Mutation (SNP) | VAF 73/501 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57472621; called by muse, mutect2, varscan2
- TMEM232 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as rs553127601; called by muse, mutect2, varscan2
- TRIML2 | c.815G>T p.R272I | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV100455999; called by muse, mutect2, varscan2
- TTLL7 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1396801743; called by muse, mutect2, varscan2
- UGT1A6 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201825340, COSV100530162; called by muse, mutect2, varscan2
- USH2A | c.7937C>T p.P2646L | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs773857989; called by muse, mutect2
- WNK2 | c.5929G>T p.A1977S (on ENST00000297954 / NM_001282394.1; = p.A1940S on NM_006648.3) | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV52962045, COSV52965316; called by muse, mutect2, varscan2
- XIRP2 | c.8541G>A p.M2847I (on ENST00000628543; = p.M3022I on NM_152381.6) | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99745470; called by muse, mutect2, varscan2
- ZNF543 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 175/555 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV58628433; called by muse, mutect2, varscan2
- ZNF835 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 218/681 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV101606388, COSV73379511; called by muse, mutect2, varscan2
- A2ML1 | c.2266G>T p.V756F | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ABCC3 | c.4462A>G p.M1488V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ADAM29 | c.81T>A p.Y27* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2506T>G p.C836G | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS14 | c.3573G>T p.W1191C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ADAMTS9 | c.3706G>T p.V1236L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AFF1 | c.2222T>A p.L741* | Nonsense Mutation (SNP) | VAF 49/193 reads (25%) | called by muse, mutect2, varscan2
- AL137230.1 | n.503G>T | Splice Region (SNP) | VAF 41/162 reads (25%) | called by muse, mutect2, varscan2
- AMER1 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- ANKRD30BL | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANO5 | c.2414+1G>T p.X805_splice | Splice Site (SNP) | VAF 50/246 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP17 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf96 | c.954del p.G319Afs*3 (on ENST00000339446; = p.G6Afs*3 on NM_001145033.2) | Frame Shift Del (DEL) | VAF 21/158 reads (13%) | called by mutect2, pindel, varscan2
- C2CD6 | c.176C>A p.T59K | Missense Mutation (SNP) | VAF 108/419 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 63/239 reads (26%) | called by muse, mutect2, varscan2
- CAVIN3 | c.227del p.N76Tfs*13 | Frame Shift Del (DEL) | VAF 89/380 reads (23%) | called by mutect2, pindel, varscan2
- CCDC54 | c.593T>A p.V198E | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CDCP1 | c.1861C>G p.L621V | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.359); called by muse, mutect2
- CDH10 | c.2114C>A p.P705Q | Missense Mutation (SNP) | VAF 151/541 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CDKN1B | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CFAP47 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CHD4 | c.5647C>G p.L1883V (on ENST00000357008 / NM_001363606.2; = p.L1893V on NM_001273.5) | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CLASRP | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 79/359 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- COLGALT2 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CPEB1 | c.1129G>C p.G377R (on ENST00000617958; = p.G317R on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRABP1 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 77/473 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CSMD1 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CSMD3 | c.10039C>A p.P3347T (on ENST00000297405 / NM_001363185.1; = p.P3178T on NM_052900.3) | Missense Mutation (SNP) | VAF 88/462 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF12L2 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF12L2 | c.1366G>T p.G456W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DICER1 | c.4685G>A p.C1562Y | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH5 | c.3281C>G p.S1094C | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- DNAH9 | c.3340del p.H1114Tfs*13 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- DSG4 | c.701A>T p.N234I | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ELF4 | c.1664C>G p.P555R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- EPHX4 | c.1024C>G p.Q342E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ESRRG | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 82/389 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EVX2 | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM9A | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FCGBP | c.6631del p.C2211Afs*12 | Frame Shift Del (DEL) | VAF 350/2548 reads (14%) | called by mutect2, varscan2
- FCRL2 | c.1226T>A p.L409H | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FGF23 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 86/561 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FLG | c.2678G>T p.S893I | Missense Mutation (SNP) | VAF 190/873 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- FNDC3B | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GATB | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLRB | c.428T>C p.L143S | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRAMD1B | c.2038del p.Q680Sfs*3 | Frame Shift Del (DEL) | VAF 22/158 reads (14%) | called by mutect2, pindel
- GRM7 | c.1698C>G p.D566E | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.092); called by muse, mutect2
- HMGB2 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IGKV3D-20 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 181/840 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAM | c.1554G>T p.W518C (on ENST00000648685 / NM_001145808.2; = p.W517C on NM_000632.4) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNB1 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF28P | n.2716A>C | Splice Region (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- KIF6 | c.1674C>A p.C558* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- KLHL10 | c.153T>A p.S51R | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP11-1 | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA2 | c.1079C>A p.A360D | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMB1 | c.2306C>A p.T769K | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- LOXL1 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LPA | c.5678T>G p.V1893G | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.4736C>T p.A1579V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2
- LYAR | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- LYAR | c.129T>A p.D43E | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, varscan2
- MEGF8 | c.3155G>T p.W1052L (on ENST00000251268 / NM_001271938.2; = p.W985L on NM_001410.3) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- METTL22 | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPLKIP | c.391dup p.R131Kfs*4 | Frame Shift Ins (INS) | VAF 64/434 reads (15%) | called by mutect2, pindel, varscan2
- MUC16 | c.26509G>C p.E8837Q | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.207); called by muse, mutect2
- MYO1C | c.2848G>T p.V950L (on ENST00000648651 / NM_001080779.2; = p.V915L on NM_033375.5) | Missense Mutation (SNP) | VAF 200/634 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NACAD | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NLGN4X | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NLRP1 | c.2551G>C p.A851P | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- OR10S1 | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- OR10W1 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OS9 | c.880dup p.Q294Pfs*12 | Frame Shift Ins (INS) | VAF 65/254 reads (26%) | called by mutect2, pindel, varscan2
- PCSK2 | c.885+1del | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- PDE11A | c.1098T>A p.C366* | Nonsense Mutation (SNP) | VAF 47/230 reads (20%) | called by muse, mutect2, varscan2
- PGR | c.2019C>A p.F673L | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2G | c.3719T>C p.L1240P (on ENST00000676171; = p.L1199P on NM_004570.5) | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PIWIL1 | c.1651G>T p.A551S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIWIL1 | c.1652C>A p.A551E | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNLIPRP2 | c.1244A>T p.Q415L (on ENST00000611850; = p.Q416L on NM_005396.5) | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- POLQ | c.2087G>T p.R696L | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- PROC | c.536-1G>T p.X179_splice | Splice Site (SNP) | VAF 79/448 reads (18%) | called by muse, mutect2, varscan2
- RBM10 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- RYR2 | c.11230A>T p.I3744F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SERPINB13 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SHANK1 | c.3459C>G p.I1153M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SIPA1L3 | c.829A>C p.T277P | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35D1 | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SLC7A10 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SMG1 | c.5089G>T p.D1697Y | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SPATA19 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SPTBN4 | c.4519C>A p.R1507S | Missense Mutation (SNP) | VAF 61/343 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STEAP1 | c.80A>T p.Y27F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SYT1 | c.1205T>C p.I402T | Missense Mutation (SNP) | VAF 122/405 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TEX51 | c.556C>T p.Q186* (on ENST00000643416; = p.G160= on NM_001322244.2) | Nonsense Mutation (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- TFAP2D | c.960T>A p.H320Q | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- THOC3 | c.619A>T p.N207Y | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THSD7B | c.3380C>A p.P1127H (on ENST00000272643; = p.P1125H on NM_001316349.2) | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMEM131 | c.2931del p.R978Gfs*22 | Frame Shift Del (DEL) | VAF 43/325 reads (13%) | called by mutect2, pindel, varscan2
- TNFAIP2 | c.1461_1462delinsA p.P488Lfs*12 | Frame Shift Del (DEL) | VAF 68/516 reads (13%) | called by pindel, varscan2*
- TRHDE | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TRHR | c.449G>T p.W150L | Missense Mutation (SNP) | VAF 70/637 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGGT1 | c.4039_4050del p.F1347_V1350del | In Frame Del (DEL) | VAF 33/189 reads (17%) | called by mutect2, pindel, varscan2
- UNC13A | c.3415C>A p.P1139T | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC5C | c.2651C>A p.T884N | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- USP5 | c.2488G>C p.V830L (on ENST00000229268 / NM_001098536.2; = p.V807L on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- WDR46 | c.70-1G>T p.X24_splice | Splice Site (SNP) | VAF 65/235 reads (28%) | called by muse, mutect2, varscan2
- WDR97 | c.4474G>T p.E1492* | Nonsense Mutation (SNP) | VAF 43/216 reads (20%) | called by muse, mutect2, varscan2
- WIPF1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 78/466 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WTIP | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- WWP1 | c.1550A>G p.H517R | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZCCHC14 | c.2236A>T p.S746C (on ENST00000268616; = p.S883C on NM_015144.3) | Missense Mutation (SNP) | VAF 93/511 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- ZIC3 | c.1228C>A p.H410N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF391 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 47/208 reads (23%) | called by muse, mutect2, varscan2
- ZNF536 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 177/910 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF714 | c.1207G>C p.G403R | Missense Mutation (SNP) | VAF 98/441 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AARS2 | c.1104A>T p.P368= | Silent (SNP) | VAF 158/725 reads (22%) | called by muse, mutect2, varscan2
- ABCA6 | c.2631T>C p.A877= | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as rs761208529; called by muse, mutect2, varscan2
- ABCB10 | c.945C>T p.A315= | Silent (SNP) | VAF 26/220 reads (12%) | called by muse, mutect2, varscan2
- ACTN2 | c.1984C>A p.R662= | Silent (SNP) | VAF 83/410 reads (20%) | called by muse, mutect2, varscan2
- ADAM2 | c.1551A>T p.S517= | Silent (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- ANK3 | c.12487C>A p.R4163= (on ENST00000280772 / NM_001320874.2; = p.R684= on NM_001149.3) | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV55058581; called by muse, mutect2, varscan2
- CSMD1 | c.6549C>T p.H2183= (on ENST00000520002; = p.H2182= on NM_033225.6) | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs776073303, COSV59394928; called by muse, mutect2, varscan2
- CTNNA2 | c.423G>T p.A141= | Silent (SNP) | VAF 44/230 reads (19%) | called by muse, mutect2, varscan2
- DDC | c.261G>A p.P87= | Silent (SNP) | VAF 48/578 reads (8%) | catalogued as rs200437940, COSV63563685; called by muse, mutect2
- DMRT1 | c.438T>G p.L146= | Silent (SNP) | VAF 66/280 reads (24%) | called by muse, mutect2, varscan2
- EXOC8 | c.1863C>A p.T621= | Silent (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- FAHD1 | c.537C>T p.I179= | Silent (SNP) | VAF 63/280 reads (23%) | catalogued as rs759635482; called by muse, mutect2, varscan2
- GALNT3 | c.429T>C p.R143= | Silent (SNP) | VAF 15/196 reads (8%) | catalogued as rs970085982, COSV67061598; called by muse, mutect2
- GDPD4 | c.1038C>T p.V346= | Silent (SNP) | VAF 35/212 reads (17%) | catalogued as rs1216822560, COSV60020185; called by muse, mutect2, varscan2
- GPC6 | c.1545A>G p.T515= | Silent (SNP) | VAF 261/796 reads (33%) | catalogued as rs956627203; called by muse, mutect2, varscan2
- GRIK1 | c.342C>G p.S114= | Silent (SNP) | VAF 63/249 reads (25%) | called by muse, mutect2, varscan2
- HAAO | c.333C>T p.T111= | Silent (SNP) | VAF 50/220 reads (23%) | catalogued as rs375595420; called by muse, mutect2, varscan2
- HCRTR2 | c.9C>A p.G3= | Silent (SNP) | VAF 87/648 reads (13%) | called by muse, mutect2, varscan2
- HCRTR2 | c.171G>T p.L57= | Silent (SNP) | VAF 112/472 reads (24%) | called by muse, mutect2, varscan2
- HPSE2 | c.921G>T p.G307= | Silent (SNP) | VAF 84/491 reads (17%) | called by muse, mutect2, varscan2
- IFI44L | c.582G>A p.L194= | Silent (SNP) | VAF 40/153 reads (26%) | called by muse, mutect2, varscan2
- IGKV1-9 | c.138G>T p.R46= | Silent (SNP) | VAF 202/980 reads (21%) | called by muse, mutect2, varscan2
- INPPL1 | c.1363C>T p.L455= | Silent (SNP) | VAF 53/266 reads (20%) | called by muse, mutect2, varscan2
- ITPRID1 | c.2940C>G p.A980= | Silent (SNP) | VAF 74/419 reads (18%) | called by muse, mutect2, varscan2
- LAMA2 | c.1080C>G p.A360= | Silent (SNP) | VAF 52/278 reads (19%) | called by muse, mutect2, varscan2
- MAGI2 | c.1017T>A p.A339= | Silent (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- MON1B | c.1047C>T p.C349= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as rs1469799192, COSV50253515; called by muse, mutect2
- MPPED2 | c.273A>G p.G91= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- MYO18B | c.7383C>A p.A2461= | Silent (SNP) | VAF 74/250 reads (30%) | called by muse, mutect2, varscan2
- MYO7B | c.681C>A p.I227= | Silent (SNP) | VAF 63/400 reads (16%) | called by muse, mutect2, varscan2
- NRXN1 | c.1020C>A p.V340= | Silent (SNP) | VAF 42/246 reads (17%) | catalogued as COSV58475481; called by muse, mutect2, varscan2
- OR2AG1 | c.441G>A p.T147= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as rs764662672, COSV56625989; called by muse, mutect2, varscan2
- P3H2 | c.267G>C p.A89= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- PAK2 | c.1215A>T p.G405= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- RREB1 | c.3963G>A p.P1321= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs770076990, COSV58558001; called by muse, mutect2, varscan2
- RYR2 | c.1839C>A p.V613= | Silent (SNP) | VAF 27/185 reads (15%) | catalogued as COSV63713736; called by muse, mutect2, varscan2
- RYR2 | c.3025C>A p.R1009= | Silent (SNP) | VAF 31/145 reads (21%) | called by muse, mutect2, varscan2
- SCG3 | c.1161A>C p.T387= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV55022196; called by muse, mutect2, varscan2
- SCN9A | c.5040T>C p.N1680= (on ENST00000303354; = p.N1669= on NM_002977.3) | Silent (SNP) | VAF 54/213 reads (25%) | catalogued as COSV57625778; called by muse, mutect2, varscan2
- SNTG1 | c.1350C>A p.I450= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99382477; called by muse, mutect2
- SPINT2 | c.183A>T p.G61= | Silent (SNP) | VAF 72/495 reads (15%) | called by muse, mutect2, varscan2
- TBC1D17 | c.1536G>C p.L512= | Silent (SNP) | VAF 155/438 reads (35%) | called by muse, mutect2, varscan2
- TEAD3 | c.309G>T p.R103= | Silent (SNP) | VAF 42/340 reads (12%) | called by muse, mutect2, varscan2
- TFAP2C | c.906G>A p.L302= | Silent (SNP) | VAF 48/383 reads (13%) | called by muse, mutect2, varscan2
- THSD7B | c.1971C>T p.D657= | Silent (SNP) | VAF 102/451 reads (23%) | catalogued as rs776659179; called by muse, mutect2, varscan2
- THSD7B | c.3381C>T p.P1127= (on ENST00000272643; = p.P1125= on NM_001316349.2) | Silent (SNP) | VAF 38/261 reads (15%) | called by muse, mutect2, varscan2
- TNFRSF6B | c.624T>C p.A208= | Silent (SNP) | VAF 36/303 reads (12%) | called by muse, mutect2, varscan2
- TRAPPC4 | c.630G>A p.E210= | Silent (SNP) | VAF 38/231 reads (16%) | catalogued as COSV100421568; called by muse, mutect2, varscan2
- USP2 | c.1659C>T p.T553= | Silent (SNP) | VAF 66/283 reads (23%) | called by muse, mutect2, varscan2
- USP26 | c.1368C>G p.L456= | Silent (SNP) | VAF 49/218 reads (22%) | catalogued as COSV100896716; called by muse, mutect2, varscan2
- WNK2 | c.5928G>T p.T1976= (on ENST00000297954 / NM_001282394.1; = p.T1939= on NM_006648.3) | Silent (SNP) | VAF 58/300 reads (19%) | called by muse, mutect2, varscan2
- ZNF683 | c.1272G>A p.R424= (on ENST00000403843; = p.R404= on NM_173574.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/238 reads (12%) | catalogued as COSV100853654; called by muse, mutect2, varscan2
- ZNF774 | c.618C>G p.P206= | Silent (SNP) | VAF 33/177 reads (19%) | catalogued as rs775593017; called by muse, mutect2, varscan2
- ACKR1 | c.-66C>G | 5'UTR (SNP) | VAF 21/325 reads (6%) | catalogued as rs1185314734; called by muse, mutect2
- AGAP7P | n.1875G>T | RNA (SNP) | VAF 49/719 reads (7%) | called by muse, mutect2, varscan2
- C7orf57 | c.-151T>A | 5'UTR (SNP) | VAF 23/254 reads (9%) | called by muse, mutect2
- CCDC74A | c.295+345C>T | Intron (SNP) | VAF 49/212 reads (23%) | called by muse, mutect2, varscan2
- CCDC88A | c.882+28G>T | Intron (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- CYBA | c.287+10del | Intron (DEL) | VAF 51/377 reads (14%) | catalogued as COSV55368834; called by mutect2, pindel, varscan2
- ERCC6 | c.1397+8385C>T | Intron (SNP) | VAF 16/172 reads (9%) | catalogued as rs1197510974; called by muse, mutect2
- HACD1 | c.375+17G>T | Intron (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- HTR2C | c.-80+17024G>C | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- LINC00868 | n.708G>T | RNA (SNP) | VAF 157/472 reads (33%) | called by muse, mutect2, varscan2
- MIR518B | n.13C>G | RNA (SNP) | VAF 47/139 reads (34%) | called by muse, mutect2, varscan2
- MIR6511A4 | chr16:18347991 G>A | 5'Flank (SNP) | VAF 60/720 reads (8%) | called by muse, mutect2
- MS4A1 | c.280-28C>A | Intron (SNP) | VAF 55/257 reads (21%) | catalogued as COSV61942613; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2445G>T | Intron (SNP) | VAF 171/690 reads (25%) | called by muse, varscan2
- NOS1AP | c.-8G>C | 5'UTR (SNP) | VAF 53/232 reads (23%) | catalogued as rs1304234843, COSV62641005; called by muse, mutect2, varscan2
- NTM | c.934+2987G>A | Intron (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- NXN | c.361-70868G>A | Intron (SNP) | VAF 20/28 reads (71%) | called by muse, mutect2, varscan2
- OR7E5P | n.137C>T | RNA (SNP) | VAF 62/329 reads (19%) | catalogued as rs747278676; called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53445T>A | Intron (SNP) | VAF 62/295 reads (21%) | catalogued as rs1307659166; called by muse, mutect2, varscan2
- PHOX2B | c.242-123T>C | Intron (SNP) | VAF 100/399 reads (25%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.330+164A>G | Intron (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- PRPH | c.1217+49C>A | Intron (SNP) | VAF 114/386 reads (30%) | called by muse, mutect2, varscan2
- PRSS1 | c.200+259G>A | Intron (SNP) | VAF 48/288 reads (17%) | called by muse, varscan2
- PSCA | c.*14C>T | 3'UTR (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- RAD21 | chr8:116874905 G>A | 5'Flank (SNP) | VAF 72/364 reads (20%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1893_1894insC | RNA (INS) | VAF 14/84 reads (17%) | called by mutect2, pindel*, varscan2
- SCML2P1 | chr18:6928460 G>T | 3'Flank (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- SHH | c.301-39C>G | Intron (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3198G>T | RNA (SNP) | VAF 75/290 reads (26%) | called by mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18605G>C | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- SSTR4 | c.-12del | 5'UTR (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- SSX3 | c.281-17G>T | Intron (SNP) | VAF 49/157 reads (31%) | called by muse, mutect2, varscan2
- STRA6 | c.180+46C>A | Intron (SNP) | VAF 62/370 reads (17%) | called by muse, mutect2, varscan2
- TLX1NB | n.1375G>A | RNA (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- WDR49 | c.487-6633C>A | Intron (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- ZFAT | c.197-2064A>T | Intron (SNP) | VAF 42/171 reads (25%) | called by muse, mutect2, varscan2
- ZFAT | c.197-2065G>T | Intron (SNP) | VAF 40/167 reads (24%) | catalogued as rs56823443; called by muse, mutect2, varscan2
- ZIC4 | c.-15-1211T>C | Intron (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- ZNF487 | c.-354G>C | 5'UTR (SNP) | VAF 53/373 reads (14%) | catalogued as rs556201579; called by muse, mutect2, varscan2
